Somatic mutation profile of tumor specimen TARGET-10-PARGFL-04B (aliquot TARGET-10-PARGFL-04B-01D) from TARGET case TARGET-10-PARGFL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,499 days).
Specimen TARGET-10-PARGFL-04B: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1516ce1a-8ce4-4afb-80c0-e4bcffc39798.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGFL-10A (Blood Derived Normal), aliquot TARGET-10-PARGFL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdd151c6-b9b8-4fff-8ef6-19de354384fb

The open-access MAF lists 45 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, 3'UTR 3, Intron 3, Frame Shift Ins 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 37/86 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRL2 | c.4046A>G p.D1349G (on ENST00000370717 / NM_001366005.1; = p.D1293G on NM_012302.4) | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54697668; called by muse, mutect2, varscan2
- ANKK1 | c.689A>C p.N230T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as rs200624485; called by muse, mutect2, varscan2
- BCL11B | c.1294T>C p.C432R (on ENST00000357195 / NM_001282237.2; = p.C361R on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100595472, COSV61736189; called by mutect2, varscan2
- DCAF12L1 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1449602853, COSV64421269; called by muse, mutect2, varscan2
- EYA1 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.052); catalogued as rs199664417, COSV100380424, COSV58177967; called by muse, mutect2, varscan2
- IBTK | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV60396468; called by muse, mutect2, varscan2
- IMPG1 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as rs754453292, COSV64063586; called by muse, mutect2, varscan2
- KDM8 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as rs111675269, COSV53733037; called by muse, mutect2, varscan2
- LCAT | c.1022T>A p.V341E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV50452227; called by mutect2, varscan2
- MEGF10 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767856393, COSV57259309; called by muse, mutect2, varscan2
- NELL1 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54344006; called by muse, mutect2, varscan2
- OPN5 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs368242075; called by muse, mutect2, varscan2
- SLC43A2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs934353646, COSV56772541; called by muse, mutect2, varscan2
- TRIM32 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs372298402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XPC | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs982648261, COSV53204833; called by muse, mutect2, varscan2
- ZNF768 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs770452825, COSV63325348; called by muse, varscan2
- ACADL | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALKBH1 | c.818G>C p.G273A | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BMP5 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf71 | c.2451_2472del p.E818Lfs*43 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- ENTPD2 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GPR148 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- H1-7 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- KLC4 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- KMT2D | c.4379dup p.L1461Tfs*30 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- LCAT | c.1020_1021insCCGCGGCGGC p.V341Pfs*29 | Frame Shift Ins (INS) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- SNAP91 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TEX15 | c.5879C>G p.S1960* (on ENST00000256246; = p.S2343* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- CNNM4 | c.1980C>T p.S660= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- EPX | c.1473C>T p.S491= | Silent (SNP) | VAF 54/104 reads (52%) | catalogued as rs368324976; called by muse, mutect2, varscan2
- FAM71C | c.330G>A p.P110= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs765707994, COSV60943445; called by muse, mutect2, varscan2
- IGHV3-23 | c.352del p.*118= | Silent (DEL) | VAF 30/140 reads (21%) | called by mutect2, pindel*, varscan2
- IQSEC3 | c.1464C>A p.V488= (on ENST00000538872 / NM_001170738.2; = p.V185= on NM_015232.1) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100407652; called by mutect2, varscan2
- KANSL1 | c.2256C>T p.D752= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs760224197; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MTUS1 | c.462C>T p.A154= | Silent (SNP) | VAF 49/152 reads (32%) | called by muse, mutect2, varscan2
- SLC15A5 | c.1473C>T p.L491= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV61365188; called by muse, mutect2, varscan2
- STK38L | c.1287G>C p.P429= | Silent (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- CHST15 | c.*1305G>A | 3'UTR (SNP) | VAF 16/37 reads (43%) | catalogued as rs1036292426; called by muse, mutect2, varscan2
- EFTUD2 | c.619+30G>T | Intron (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- PCDH9 | c.*54C>A | 3'UTR (SNP) | VAF 8/16 reads (50%) | catalogued as COSV60582487; called by mutect2, varscan2
- RPL23 | c.340+68A>G | Intron (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- SPRYD4 | c.*6244G>A | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- SYTL2 | c.1615+1221T>A | Intron (SNP) | VAF 53/136 reads (39%) | called by muse, mutect2, varscan2
